Surgical pathology report (de-identified scan), TCGA case TCGA-KN-8425, project TCGA-KICH (Kidney Chromophobe), tissue source site Harvard, specimen TCGA-KN-8425-01A (Primary Tumor).

[page 1 of 2]
PATHOLOGIC DIAGNOSIS:

A: LEFT KIDNEY:

RENAL CELL CARCINOMA, chromophobe type, 6.0 cm.

The tumor is confined to the kidney.

Fuhrman grade II of IV.

Vascular, ureteric and soft tissue margins are negative for tumor.

No lymphovascular invasion identified.

AJCC (6th edition): T1b Nx Mx.

NOTE: A renal pathology report evaluating unaffected renal parenchyma will be reported as an addendum.

CLINICAL DATA:

History: None given.

Operation: Laparoscopic left radical nephrectomy.

Operative Findings: None given.

Clinical Diagnosis: Left renal mass.

TIS: UZ SUBMITTED:

A/1 Left kidney.

GROSS DESCRIPTION:

The specimen is received fresh, labeled with the patient's name, unit number, and "H. Left kidney", and consists of 586 gm, 23.0 x 12.8 x 6.0 cm left radical nephrectomy specimen, to include left kidney (15.5 x 9.0 x 4.8 cm), with 6.5 x 2.0 x 1.1 cm left adrenal gland, attached surrounding adipose tissue, and a 13.7 x 3.5 cm patch of Gerota's fascia is present, and has been inked blue. Hilum region exhibits 7.2 cm ureter (diameter 2.4 cm), 1.8 cm artery (diameter 1.5 cm), and 1.1 cm renal vein (maximum diameter 1.6 cm). The specimen has been entirely inked and bisected, revealing a circumscribed, partially encapsulated tan/pink to tan/yellow (6.4 x 3.7 x 2.4 cm) abutting and expanding but not grossly invading the renal capsule, 2.2 cm from the closest black inked margin, and abutting the renal pelvis. Mass is 10.0 cm from the ureteral margin, 4.0 cm to the arterial margin, and 3.2 cm from the renal vein margin. Mass demonstrates central focal necrosis, (< 25% of surfaces), and focal calcification (1.5 cm), and scant hemorrhage located within the upper pole. Note: Tissue allocation for specimen states closest black inked margin as within 2.2 cm; upon further sectioning of the tumor, closest black inked margin is within 0.5 cm. This tissue is freely mobile over the underlying expanded renal capsule. Remaining renal parenchyma is grossly unremarkable, with distinct cortical medullary junction and no additional lesions grossly. Ureterum is likewise unremarkable. Adrenal gland is grossly uninvolved by tumor, and is received disrupted but is otherwise unremarkable (questionably complete). Representative tumor has been sent for EM, cytogenetics, and tissue bank. Representative normal renal parenchyma and adrenal gland have submitted to tissue bank. Representative normal renal parenchyma (cortex) has been submitted for EM and IF.

- Mi ro A1: Vascular, ureteral margin, 3 frags. [REDACTED]
Mi ro A2: Tissue in cassette designated "T1", 1 frag, [REDACTED]
Mi ro A3: Tumor renal capsule, closest black inked margin 3 frags, [REDACTED]
Mi ro A4: Tumor and surrounding uninvolved renal parenchyma, 2 frags [REDACTED]
Mi ro A5: Focally calcified tumor (following decal), 1 frag, [REDACTED]
Mi ro A6: Uninvolved renal parenchyma, uninvolved adrenal gland, 2 frags, [REDACTED]
RSS.

[page 2 of 2]
By his/her signature below, the senior physician certifies that he/she personally conducted a microscopic examination ("gross only" exam if so stated) of the described specimen(s) and rendered or confirmed the diagnosis(es) related thereto.

PATHOLOGIC DIAGNOSIS

EVALUATION OF THE KIDNEY PARENCHYMA NOT INVOLVED BY TUMOR:

NEPHRECTOMY SPECIMEN

KIDNEY PARENCHYMA WITHOUT SIGNIFICANT PATHOLOGICAL CHANGES (SEE NOTE)

ARTERIAL AND ARTERIOLAR SCLEROSIS, WITH SUBINTIMAL HYALINOSIS, MILD TO MODERATE (SEE NOTE)

NOTE:

The kidney parenchyma of this nephrectomy specimen does not reveal significant changes on the glomeruli or of the tubulointerstitial compartment; there is no evidence for an active glomerular inflammatory process or tubulointerstitial injury. The biopsy shows only mild to moderate chronic vascular injury.

MICROSCOPIC DESCRIPTION:

The sample consists of kidney cortex and medulla. There are up to one hundred (100) glomeruli present in the sample submitted for light microscopy. Glomeruli with global sclerosis are not recognized. The glomeruli show a preserved architecture, with preservation of the mesangial matrix and cellular elements. There is no evidence of active cellular proliferation or inflammation. On PAS and Jones' silver methenamine stain, the glomerular basement membranes appear delicate, without significant irregularities. No double contours or "spike-like" lesions are recognized. Tubules reveal mild vacuolization, with moderate amount of hyaline casts in the distal tubules. There is mild tubular atrophy. The interstitium reveals also mild fibrosis. Less than 5% of the sample shows tubular atrophy and interstitial fibrosis, as evidenced on the trichrome stains (AFOG). Arteries reveal moderate intimal. Afferent and efferent arterioles show mild sclerosis and hyaline deposits in the vessel walls.

Source: NCI Genomic Data Commons file b44d888f-e9ba-4368-bd2b-6ecb87342501 (TCGA-KN-8425.6C97D5A0-8519-4D0C-AE9D-065019D53621.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).